FM case AD12354 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/228faf3d-d765-4e0a-8ec4-79f6b429898e

Female, 49.9 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the anal canal. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
